Somatic mutation profile of tumor specimen TCGA-5K-AAAP-01A (aliquot TCGA-5K-AAAP-01A-11D-A423-09) from TCGA case TCGA-5K-AAAP, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 54.6 years (19,939 days).
Specimen TCGA-5K-AAAP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e035e711-4474-4bdc-8aec-d9dbb7ea06de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5K-AAAP-10A (Blood Derived Normal), aliquot TCGA-5K-AAAP-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8afeec6-b2dc-4475-b167-f481a19c8fea

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 78/389 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- ALOX5 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs919359268; called by muse, mutect2, varscan2
- IGHV3-72 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.013); catalogued as rs765501202, COSV70409619; called by muse, mutect2, varscan2
- JAG1 | c.2191T>G p.C731G | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM993755; called by mutect2, varscan2
- PARP15 | c.1531G>T p.D511Y (on ENST00000464300 / NM_001113523.3; = p.D277Y on NM_152615.2) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1280714259, COSV59972433; called by mutect2, varscan2
- PCSK5 | c.4724G>T p.G1575V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs535037527; called by muse, mutect2, varscan2
- SYT7 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs775675185, COSV55655931; called by muse, mutect2, varscan2
- ABTB2 | c.668T>C p.I223T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- CBWD5 | c.1067G>T p.R356L (on ENST00000382405 / NM_001330668.1; = p.R308L on NM_001024916.3) | Missense Mutation (SNP) | VAF 56/794 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, mutect2
- GALNT17 | c.663G>T p.Q221H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MARCHF7 | c.1859T>G p.I620S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MMRN1 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- PPFIA3 | c.1931dup p.D644Efs*40 | Frame Shift Ins (INS) | VAF 29/113 reads (26%) | called by mutect2, pindel, varscan2
- SACS | c.4498A>G p.R1500G | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- ZNF638 | c.2114A>G p.D705G | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATG9A | c.192C>A p.I64= | Silent (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- NBEA | c.4230A>C p.P1410= | Silent (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- OR6C65 | c.238C>T p.L80= | Silent (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- TRBC2 | c.27C>T p.P9= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs531367168; called by muse, mutect2, varscan2
